Somatic mutation profile of tumor specimen 0DA2YJ from CCDI case PBBJJE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 11.9 years (4,329 days).
Specimen 0DA2YJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3602a7e-a30c-44eb-a45e-e55e81d9b4a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA2YK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f8fb6b3-51cb-4ba5-8f66-286040693bc5

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SEMA3E | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 130/435 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064796805; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSHZ2 | c.1981G>A p.G661S | Missense Mutation (SNP) | VAF 109/418 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV61588372; called by muse, mutect2, varscan2
- NPIPB2 | c.998A>G p.E333G (on ENST00000399147; = p.E193G on NM_001355514.1) | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.944); called by muse, varscan2
- NPHS1 | c.2406G>A p.R802= | Silent (SNP) | VAF 107/468 reads (23%) | called by muse, mutect2, varscan2
- RDX | c.1091-40G>T | Intron (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
